Gene-level copy-number profile of tumor specimen TCGA-GC-A4ZW-01A from TCGA case TCGA-GC-A4ZW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 71.1 years (25,964 days).
Specimen TCGA-GC-A4ZW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.0fe8af92-aa2d-46dc-8433-31fecb553956.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,998 have no estimate.
https://portal.gdc.cancer.gov/files/5a7c08f1-e610-40a7-8f0a-f607e6a23f2e

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 416; copy number 2: 1,625; copy number 3: 2,454; copy number 4: 16,064; copy number 5: 16,272; copy number 6: 12,630; copy number 7: 7,164.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GC-A4ZW-01A-11D-A26L-01): tumor purity 0.85, ploidy 5.25, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 416. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
